Somatic mutation profile of tumor specimen TCGA-BC-A8YO-01A (aliquot TCGA-BC-A8YO-01A-11D-A36X-10) from TCGA case TCGA-BC-A8YO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.2 years (24,189 days).
Specimen TCGA-BC-A8YO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc84fcf4-3d9b-4602-8360-0c618afc60ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A8YO-10A (Blood Derived Normal), aliquot TCGA-BC-A8YO-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820e3bc9-6d96-4ffc-bb08-02bcc9e1c02b

The open-access MAF lists 75 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Frame Shift Del 8, Splice Region 3, Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1, Nonstop Mutation 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOD1 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV99603497; called by muse, mutect2, varscan2
- C10orf90 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.26); PolyPhen benign (0.306); catalogued as COSV99504743; called by muse, mutect2, varscan2
- CACHD1 | c.3511G>C p.V1171L | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV99261822, COSV99262929; called by muse, mutect2, varscan2
- CEP126 | c.2918A>G p.N973S | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.637); catalogued as rs1291771648, COSV99681303; called by muse, mutect2
- CERS4 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99250742; called by muse, mutect2, varscan2
- COL10A1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99684339; called by muse, mutect2, varscan2
- CPSF3 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.069); catalogued as rs775413626, COSV99433103; called by muse, mutect2, varscan2
- DNAI2 | c.1725G>A p.Q575= | Splice Region (SNP) | VAF 52/129 reads (40%) | catalogued as COSV100209960; called by muse, mutect2, varscan2
- DOCK6 | c.2802C>G p.F934L | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.88); catalogued as COSV99626307; called by muse, mutect2, varscan2
- EPN1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369409343; called by muse, mutect2, varscan2
- EVC2 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as rs139717271; called by muse, mutect2, varscan2
- FAM135B | c.410C>A p.T137K | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV50521953, COSV99356912; called by muse, mutect2, varscan2
- FAM222A | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100734570, COSV62724191; called by muse, mutect2, varscan2
- FLG | c.5053C>A p.H1685N | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as COSV100911913; called by muse, mutect2, varscan2
- FN1 | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.828); catalogued as COSV100117797; called by muse, mutect2, varscan2
- FXR1 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99976569; called by muse, varscan2
- GNB1 | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101060840; called by muse, mutect2, varscan2
- GTF2I | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100259787; called by muse, mutect2, varscan2
- H4C3 | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100619617; called by muse, mutect2
- HCN4 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56087567, COSV99984033; called by muse, mutect2, varscan2
- IGF1R | c.3381C>A p.N1127K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99157146; called by muse, mutect2, varscan2
- KEAP1 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260458, COSV50275012, COSV50315065; called by muse, mutect2, varscan2
- MAOB | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956183; called by muse, mutect2, varscan2
- MAST1 | c.2110T>C p.F704L | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99263440; called by muse, mutect2, varscan2
- MYH6 | c.1410C>T p.D470= | Splice Region (SNP) | VAF 39/95 reads (41%) | catalogued as rs139886074; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NID2 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs780404034, COSV53499514; called by muse, mutect2, varscan2
- OLFML2B | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1260173313, COSV99668724; called by muse, mutect2, varscan2
- PCDH15 | c.1963G>T p.G655* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV100225219; called by muse, mutect2, varscan2
- PLEKHH2 | c.2747T>C p.V916A | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99174972; called by muse, mutect2, varscan2
- PPFIA1 | c.2002A>C p.S668R | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99557850; called by muse, mutect2, varscan2
- PREB | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99574703; called by muse, mutect2, varscan2
- PRPF18 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100187209; called by muse, mutect2, varscan2
- PSG2 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61547309; called by muse, mutect2, varscan2
- RAD23B | c.1229G>T p.*410Lext*62 | Nonstop Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV100787754, COSV63659638; called by muse, mutect2, varscan2
- RBM22 | c.1255A>C p.S419R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.207); catalogued as COSV99556106; called by muse, mutect2, varscan2
- RMI1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100366406; called by muse, mutect2, varscan2
- RRP9 | c.644C>G p.A215G | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99232590; called by muse, mutect2, varscan2
- RYR3 | c.6171del p.N2058Tfs*3 | Frame Shift Del (DEL) | VAF 81/231 reads (35%) | catalogued as COSV66789446; called by mutect2, pindel, varscan2
- SLC25A36 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs757985146, COSV100149180; called by muse, mutect2, varscan2
- SLC6A5 | c.1872T>C p.G624= | Splice Region (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100117060; called by muse, mutect2, varscan2
- TECTA | c.5513C>A p.T1838N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99880926; called by muse, mutect2
- TERB2 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV100546610; called by muse, mutect2, varscan2
- TTC23 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 40/100 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100019118; called by muse, mutect2, varscan2
- TUSC3 | c.175T>C p.W59R | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101142302; called by muse, mutect2, varscan2
- VSIG2 | c.704C>G p.T235S | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as rs560008973, COSV99423394; called by muse, mutect2, varscan2
- WDFY3 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 164/436 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99884846; called by muse, mutect2, varscan2
- XKR8 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100872128; called by muse, mutect2, varscan2
- ZNF331 | c.551A>T p.E184V | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99467698; called by muse, mutect2, varscan2
- ZNF816 | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99554663; called by muse, mutect2, varscan2
- ADCY5 | c.3746del p.M1249Rfs*2 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, varscan2
- ALB | c.1649_1652del p.Q550Lfs*7 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by pindel, varscan2
- CEP126 | c.1784del p.I595Kfs*21 | Frame Shift Del (DEL) | VAF 58/169 reads (34%) | called by mutect2, pindel, varscan2
- HECTD3 | c.1175del p.R392Hfs*5 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- IGHV4-4 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LILRB2 | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- PDE5A | c.1172del p.L391* | Frame Shift Del (DEL) | VAF 82/193 reads (42%) | called by mutect2, varscan2
- SYNPO2 | c.1264del p.D422Tfs*14 | Frame Shift Del (DEL) | VAF 106/263 reads (40%) | called by mutect2, pindel, varscan2
- TP53 | c.687_692del p.T230_T231del | In Frame Del (DEL) | VAF 33/51 reads (65%) | called by mutect2, pindel, varscan2
- UBE2D3 | c.112dup p.M38Nfs*4 | Frame Shift Ins (INS) | VAF 208/609 reads (34%) | called by mutect2, pindel, varscan2
- WDR36 | c.1520del p.N507Tfs*4 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | called by mutect2, pindel, varscan2
- BTBD9 | c.1434G>A p.P478= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as rs181693343, COSV58422155; called by muse, mutect2, varscan2
- COL28A1 | c.2163A>T p.P721= | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as COSV101258824; called by muse, mutect2, varscan2
- CTNNA2 | c.2559C>T p.S853= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV100561619; called by muse, varscan2
- DYTN | c.138T>C p.R46= | Silent (SNP) | VAF 76/180 reads (42%) | catalogued as COSV101510889; called by muse, mutect2, varscan2
- GLRA3 | c.543T>C p.D181= | Silent (SNP) | VAF 216/518 reads (42%) | catalogued as COSV99927910; called by muse, mutect2, varscan2
- LILRA5 | c.546C>T p.S182= | Silent (SNP) | VAF 77/150 reads (51%) | catalogued as COSV100007035; called by muse, mutect2, varscan2
- MCM5 | c.474C>T p.A158= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99331860; called by muse, mutect2, varscan2
- MGLL | c.57C>A p.L19= (on ENST00000398104 / NM_001003794.2; = p.L29= on NM_007283.6) | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV54027784, COSV99412190; called by muse, mutect2, varscan2
- NAXE | c.336G>T p.L112= | Silent (SNP) | VAF 62/99 reads (63%) | catalogued as COSV100963991; called by muse, mutect2, varscan2
- NR2E1 | c.873C>A p.I291= | Silent (SNP) | VAF 68/150 reads (45%) | catalogued as COSV100934610; called by muse, mutect2, varscan2
- PFN4 | c.261C>T p.N87= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs774869541, COSV100500420; called by muse, mutect2, varscan2
- PRDM13 | c.1278G>T p.A426= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100980561; called by muse, mutect2, varscan2
- SLC6A19 | c.1314C>T p.G438= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as rs141604151; called by muse, mutect2, varscan2
- SLIT2 | c.1716T>C p.D572= | Silent (SNP) | VAF 264/611 reads (43%) | catalogued as COSV99885999; called by muse, mutect2, varscan2
- CPLANE1 | c.*5393C>G | 3'UTR (SNP) | VAF 64/147 reads (44%) | catalogued as COSV99951255; called by muse, mutect2, varscan2
